Surgical pathology report (de-identified scan), TCGA case TCGA-KS-A41F, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Of Michigan, specimen TCGA-KS-A41F-01A (Primary Tumor).

PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

NAME: [REDACTED]

BIRTHDATE: [REDACTED]

PATIENT NBR: [REDACTED]

PAT TYPE:

SEX:

ADM DATE: [REDACTED]

ACCESSION: [REDACTED]

OPER DATE:

REQ DOC: [REDACTED]

PROCEDURE: SPHS

VERIFIED BY: [REDACTED]

Source: Neck-thyroid. -year-old with papillary thyroid

PROCEDURE: SPGD

VERIFIED BY: [REDACTED]

1. "Total thyroidectomy." Received fresh is a 23 gram thyroidectomy, right lobe 4.6 x 2.8 x 1.3 cm and left lobe 4.2 x 2.6 x 1.6 cm. The thyroid is covered by pink-grey capsule. The right lobe is inked black and the left lobe is inked blue. Upon sectioning the cut surface is a glistening red. It is remarkable for a 2.2 x 1.9 x 1.7 cm tan-pink tumor in the superior pole of the left lobe that abuts the capsule. Adjacent to the left lobe of the thyroid is a 2 x 1.5 x 0.5 cm portion of adipose. Seven possible lymph nodes are identified ranging up to 0.5 cm.

1A-D. Tumor.

1E. Normal left lobe.

1F. Normal right lobe.

1G. Possible lymph nodes.

ICD-03

Carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS

C73.9

7-23-12 RD

PROCEDURE: SPDX

VERIFIED BY: [REDACTED]

1. Thyroid, excision: Papillary thyroid carcinoma, 2.2 cm, well differentiated, involving the left lobe. Tumor closely approximates the inked surgical margin. Metastatic papillary carcinoma in four of seven lymph nodes (4/7).

I, [REDACTED] the signing staff pathologist, have personally examined and interpreted the slides from this case.

7/16/12

Source: NCI Genomic Data Commons file 32402739-c60d-4a11-a2aa-00e4fcfaed19 (TCGA-KS-A41F.4EF861C5-0F5E-41D2-AB5A-F029E9E9F5D3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).